Somatic mutation profile of tumor specimen TCGA-28-5214-01A (aliquot TCGA-28-5214-01A-01D-1486-08) from TCGA case TCGA-28-5214, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.4 years (19,520 days).
Specimen TCGA-28-5214-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfebbdbd-f68d-42f6-a747-6e94d999aa40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-5214-10A (Blood Derived Normal), aliquot TCGA-28-5214-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d21805b6-f571-42e2-ada1-4bbb8d85a143

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 11, Nonsense Mutation 2, RNA 2, Splice Region 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG7 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as rs771209708, COSV56295119; called by muse, mutect2, varscan2
- CDH9 | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV50263484; called by muse, mutect2
- CDX4 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 39/61 reads (64%) | catalogued as COSV65171416; called by muse, mutect2, varscan2
- CFAP221 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 127/345 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs375100921; called by muse, mutect2, varscan2
- EPB41L4B | c.1222A>G p.T408A | Missense Mutation (SNP) | VAF 103/320 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs1187008954, COSV65796430; called by muse, mutect2, varscan2
- EPHX4 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 113/347 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64889306; called by muse, mutect2, varscan2
- GJC1 | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 108/455 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57910797; called by muse, mutect2, varscan2
- INHBA | c.604A>T p.S202C | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV54220514; called by muse, mutect2, varscan2
- INTS11 | c.126C>T p.D42= | Splice Region (SNP) | VAF 62/191 reads (32%) | catalogued as rs900368991, COSV59671973, COSV59673107; called by muse, mutect2, varscan2
- LINGO2 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 37/100 reads (37%) | catalogued as rs1486718797, COSV58058566; called by muse, mutect2, varscan2
- MACF1 | c.12872C>T p.A4291V (on ENST00000372915; = p.A2224V on NM_012090.5) | Missense Mutation (SNP) | VAF 63/181 reads (35%) | catalogued as rs573837366, COSV57104402; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MC4R | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs142837166, CM035774, COSV100236168; called by muse, mutect2, varscan2
- MIPEP | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs148780512; called by muse, mutect2
- NR2F2 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67683340; called by muse, mutect2, varscan2
- PCDHGA9 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as rs370966293, COSV53921726; called by muse, mutect2, varscan2
- PSG9 | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 36/770 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1373009009, COSV52484217; called by muse, mutect2
- SCN11A | c.4075G>A p.V1359M | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs777323474, COSV56567930, COSV56568066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMURF1 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759288763, COSV62815872; called by muse, mutect2, varscan2
- SYNGR4 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV61225196; called by muse, mutect2, varscan2
- TMEM120A | c.530T>G p.I177S | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV58693704; called by muse, mutect2, varscan2
- UGT2B15 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 110/288 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57733733; called by muse, mutect2, varscan2
- VPS13C | c.9173G>A p.R3058H (on ENST00000644861 / NM_020821.3; = p.R3015H on NM_017684.5) | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as rs150364963; called by muse, mutect2, varscan2
- WDFY3 | c.9318G>C p.E3106D | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV55697066; called by muse, mutect2
- ZNF564 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV59434718; called by muse, mutect2, varscan2
- IK | c.418del p.A140Qfs*7 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- FOXN1 | c.1821A>C p.A607= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs1262298366, COSV56881182; called by muse, mutect2, varscan2
- FSTL5 | c.819A>G p.Q273= | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV60187582; called by muse, mutect2, varscan2
- HDGFL2 | c.93C>T p.G31= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as rs775237759, COSV56682163; called by muse, mutect2, varscan2
- HIVEP1 | c.3423C>T p.S1141= | Silent (SNP) | VAF 54/160 reads (34%) | catalogued as COSV65098521, COSV65100121; called by muse, mutect2, varscan2
- LILRA1 | c.183T>C p.Y61= | Silent (SNP) | VAF 86/352 reads (24%) | catalogued as rs774697016, COSV52179547; called by muse, varscan2
- MAGEA8 | c.792G>A p.A264= | Silent (SNP) | VAF 143/205 reads (70%) | catalogued as rs376840959, COSV54063614; called by muse, mutect2, varscan2
- MAP3K11 | c.2070G>T p.P690= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV58418989, COSV58420957; called by muse, mutect2, varscan2
- NPHP4 | c.2616A>G p.K872= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV65394171; called by muse, mutect2, varscan2
- PGK2 | c.513C>T p.R171= | Silent (SNP) | VAF 55/179 reads (31%) | catalogued as rs147140024; called by muse, mutect2, varscan2
- PIK3CG | c.1053C>T p.T351= | Silent (SNP) | VAF 74/347 reads (21%) | catalogued as rs550240865, COSV63247175; called by muse, mutect2, varscan2
- USH2A | c.8028G>A p.P2676= | Silent (SNP) | VAF 76/173 reads (44%) | catalogued as rs766443785, COSV56349587; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FMN1 | c.2044-2367T>C | Intron (SNP) | VAF 49/160 reads (31%) | catalogued as COSV57920493; called by muse, mutect2, varscan2
- HERC2P3 | n.503C>T | RNA (SNP) | VAF 8/64 reads (13%) | catalogued as rs1321647389; called by mutect2, varscan2
- MIR15A | n.23A>C | RNA (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
